Surgical pathology report (de-identified scan), TCGA case TCGA-XE-AANH, project TCGA-TGCT (Testicular Germ Cell Tumors), specimen TCGA-XE-AANH-01A (Primary Tumor).

[page 1 of 3]
Surgical Pathology Report

Patient Name:

Med. Rec. #:

DOB:

Gender:

Location:

Requestor:

Date Collected:

Date Received:

Date Reported:

Specimen(s) Received

Right testicular Mass

Clinical History

Not stated.

Pre-Operative Diagnosis

Right testicular cancer

Gross Description

Right testicular Mass: Received fresh designated "right testicular mass" is a 100-gram radical orchiectomy specimen measuring 19.0 x 5.0 x 4.37 cm in overall dimensions. The testis measures 5.0 x 4.3 x 8.0 cm. The spermatic cord measures 10.5 cm in length and 0.8 cm in diameter. Sectioning through the testicle reveals a 7.5 x 4.5 x 4.0 cm mass within irregular, variegated cut surface replacing most of the testicular parenchyma. The cut surface has areas of yellow nodularity, tan nodularity, and focal hemorrhagic areas. Tumor is confined to the testis and does not involve the epididymis. Tumor does not penetrate the tunica albuginea or the tunica vaginalis. Cassette summary as follows:

1. Spermatic cord resection margin
2. Mid and proximal spermatic cord
- 3-9 Representative portions of tumor
- 10 Tumor and epididymis
- 11 Apparent normal parenchyma

Date of Dictation:

Gross Description by:

abf *red-0.3*
Seminoma NOS 9061/3
path *Mixed germ cell tumor*
9085/3
Site: Testis NOS
Q62.9
9/23/11/4

Microscopic Description

Performed.

Final Pathologic Diagnosis

Right testicular Mass:

- Mixed germ cell tumor comprised of:
Seminoma, classical type- 85% of tumor mass
Mature teratoma- 15% of tumor mass
- Tumor measures 7.5 x 4.5 x 4.0 cm and is limited to the testis
- Tumor does not penetrate tunica albuginea or involve the epididymis
- No vascular or lymphatic invasion identified.
- Remaining testis show atrophy

[page 2 of 3]
Date Collected:
Date Received:
Date Reported:

Location:
Requestor:

Specimen(s) Received:
Right testicular Mass

Date Ordered:
Status: Signed Out

Addendum Diagnosis
Spermatic cord margin is negative.

Attending Pathologist(s):

***Electronically Released By

Page 1 of 1

100% seminoma, pw dx discrepancy form

[page 3 of 3]
TCGA Pathologic Diagnosis Discrepancy Form

V4.00

Instructions: The TCGA Pathologic Diagnosis Discrepancy Form should be completed when the pathologic diagnosis documented on the initial pathology report for a case submitted for TCGA is inconsistent with the diagnosis provided on the Case Quality Control Form completed for the submitted case.

Tissue Source Site (TSS): _____ TSS Identifier: _____ TSS Unique Patient Identifier: _____

Completed By (Interviewer Name on OpenClinica): _____ Completed Date: _____

Diagnosis Information

#	Data Element	Entry Alternatives	Working Instructions
1	Pathologic Diagnosis Provided on Initial Pathology Report	Seminoma 85%, Mature Teratoma 15%	Provide the diagnosis/ histologic subtype(s) documented on the initial pathology report for this case. If the histology for this case is mixed, provide all listed subtypes.
2	Histologic features of the sample provided for TCGA, as reflected on the CQCF.	Seminoma 100%	Provide the histologic features selected on the TCGA Case Quality Control Form completed for this case.

Discrepancy between Pathology Report and Case Quality Control Form

3	Provide the reason for the discrepancy between the pathology report and the TCGA Case Quality Control Form.	histologic heterogeneity characteristic of mixed germ cell tumors	Provide a reason describing why the diagnosis on the initial pathology report for this case is not consistent with the diagnosis selected on the TCGA Case Quality Control Form.
4	Name of TSS Reviewing Pathologist or Biorepository Director	_____	Provide the name of the pathologist who reviewed this case for TCGA.

I acknowledge that the above information provided by my institution is true and correct and has been quality controlled.

TSS Reviewing Pathologist or Biorepository Director

Date

I acknowledge that the above information provided by my institution is true and correct and has been quality controlled. The Attending Pathologist or the Department Chairman has been informed or is aware of the above discrepancy in diagnoses.

Principal Investigator Signature

Date

Source: NCI Genomic Data Commons file bb42061f-cfda-4f07-8000-b0672206aae4 (TCGA-XE-AANH-01A.pdf), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).